Somatic mutation profile of tumor specimen MMRF_2734_1_BM_CD138pos (aliquot MMRF_2734_1_BM_CD138pos_T1_KHS5U_L14881) from MMRF case MMRF_2734, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.3 years (20,561 days).
Specimen MMRF_2734_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0177b3b6-5128-4ebe-afb8-fffc8c015fea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2734_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2734_1_PB_WBC_C3_KHS5U_L14882; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0718570a-e9df-4cf9-bf73-e423b0a42f6c

The open-access MAF lists 123 somatic variants for this specimen: 48 protein-altering or splice-affecting, 21 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 32, Silent 21, Intron 10, 5'UTR 5, 3'Flank 4, Nonsense Mutation 4, 5'Flank 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 20/162 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ADCY1 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 25/455 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs1198951140; called by muse, mutect2
- AGBL1 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV69815187; called by muse, mutect2
- AP2A2 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.215); catalogued as rs768577549; called by muse, mutect2
- CTSL | c.826C>A p.H276N | Missense Mutation (SNP) | VAF 119/279 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58246429; called by muse, mutect2, varscan2
- DIP2C | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 9/117 reads (8%) | catalogued as rs1290518085; called by muse, mutect2
- ELL | c.224G>C p.R75P | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs754797656; called by muse, mutect2, varscan2
- IGHV2-70 | c.345C>A p.Y115* | Nonsense Mutation (SNP) | VAF 22/28 reads (79%) | catalogued as rs10144402; called by muse, varscan2
- IGHV3-53 | c.154T>A p.Y52N | Missense Mutation (SNP) | VAF 128/535 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs781969860; called by muse, mutect2, varscan2
- KRTAP29-1 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs372411577, COSV104429861; called by muse, mutect2, varscan2
- MOV10L1 | c.865A>C p.T289P | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.192); catalogued as COSV53175615; called by muse, mutect2, varscan2
- MYO7B | c.443A>G p.N148S | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.458); catalogued as rs868837125; called by muse, mutect2
- NCR1 | c.636C>T p.G212= | Splice Region (SNP) | VAF 132/306 reads (43%) | catalogued as rs770811879, COSV52555460, COSV99401131; called by muse, mutect2, varscan2
- NKD1 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373392827; called by muse, mutect2, varscan2
- OR8S1 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 12/97 reads (12%) | PolyPhen benign (0.001); catalogued as rs1386637720; called by muse, mutect2, varscan2
- PCARE | c.3479C>A p.A1160E | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.288); catalogued as COSV100527994; called by muse, mutect2, varscan2
- PNMA8A | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as rs753466230; called by muse, mutect2
- PPL | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201735222; called by muse, mutect2, varscan2
- RNF113B | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99940402; called by muse, mutect2
- SEMA3E | c.257T>C p.I86T | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV57088258; called by muse, mutect2
- ST6GAL2 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | PolyPhen possibly damaging (0.728); catalogued as rs1443893427, COSV64528114; called by muse, mutect2, varscan2
- VEGFC | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768314100; called by muse, mutect2, varscan2
- ACAP1 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- ACOX3 | c.158C>G p.S53* | Nonsense Mutation (SNP) | VAF 137/292 reads (47%) | called by muse, mutect2, varscan2
- ARIH1 | c.1288T>G p.F430V | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ATPAF2 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRD9 | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 105/161 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- C3orf49 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 354/593 reads (60%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DMBT1 | c.5792A>G p.Y1931C (on ENST00000338354 / NM_001377530.1; = p.Y1174C on NM_004406.3) | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- EPHA4 | c.2945G>A p.R982K | Missense Mutation (SNP) | VAF 29/490 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.057); called by muse, mutect2
- FAM214B | c.338T>G p.V113G | Missense Mutation (SNP) | VAF 122/256 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOXK1 | c.2183G>A p.G728E | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2
- GPKOW | c.904T>G p.L302V | Missense Mutation (SNP) | VAF 46/54 reads (85%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LPIN1 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO5A | c.2140A>T p.M714L | Missense Mutation (SNP) | VAF 116/378 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NPHP4 | c.3115G>A p.D1039N | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.974); called by muse, mutect2
- PHLDB1 | c.3370A>T p.I1124F | Missense Mutation (SNP) | VAF 209/316 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PIK3R5 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2
- PITPNM3 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- PLCH1 | c.3382C>T p.L1128F (on ENST00000340059 / NM_001130960.2; = p.L1120F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/297 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2
- PLEKHG3 | c.3425A>G p.D1142G (on ENST00000394691; = p.D1198G on NM_001308147.2) | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- SETD7 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX15 | c.7106A>G p.K2369R (on ENST00000256246; = p.K2752R on NM_001350162.2) | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TGFB1 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- TRIM14 | c.799C>G p.R267G | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TSKS | c.1660A>T p.M554L | Missense Mutation (SNP) | VAF 21/334 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2
- WDFY3 | c.9048A>C p.K3016N | Missense Mutation (SNP) | VAF 78/161 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ALDH1L1 | c.93T>C p.T31= | Silent (SNP) | VAF 38/129 reads (29%) | called by muse, mutect2, varscan2
- APBA1 | c.786C>T p.D262= | Silent (SNP) | VAF 24/347 reads (7%) | called by muse, mutect2
- ASB4 | c.6C>T p.D2= | Silent (SNP) | VAF 81/340 reads (24%) | catalogued as rs146716091; called by muse, mutect2, varscan2
- CEP290 | c.2241T>C p.T747= | Silent (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- CGREF1 | c.456C>T p.P152= | Silent (SNP) | VAF 66/159 reads (42%) | catalogued as rs780406551; called by muse, mutect2, varscan2
- CSMD3 | c.7812A>G p.G2604= (on ENST00000297405 / NM_001363185.1; = p.G2500= on NM_052900.3) | Silent (SNP) | VAF 30/193 reads (16%) | catalogued as COSV52165619; called by muse, mutect2, varscan2
- FCGBP | c.2682C>T p.C894= | Silent (SNP) | VAF 22/379 reads (6%) | called by muse, mutect2
- FIBCD1 | c.930C>T p.T310= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs780867280, COSV53394332; called by muse, mutect2, varscan2
- HAND2 | c.276G>A p.L92= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs542409297, COSV100854233, COSV64018267; called by muse, mutect2, varscan2
- IBTK | c.2856A>G p.E952= | Silent (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.339G>T p.T113= | Silent (SNP) | VAF 22/24 reads (92%) | catalogued as rs1441146570; called by muse, varscan2
- IGKV4-1 | c.216G>T p.L72= | Silent (SNP) | VAF 53/63 reads (84%) | catalogued as rs371877227; called by muse, mutect2, varscan2
- MAGEB16 | c.258T>G p.A86= | Silent (SNP) | VAF 47/48 reads (98%) | called by muse, mutect2, varscan2
- MAPK12 | c.273C>T p.D91= | Silent (SNP) | VAF 79/173 reads (46%) | catalogued as rs750170817; called by muse, mutect2, varscan2
- MSN | c.1002G>A p.E334= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs113359990, COSV64303140; called by muse, varscan2
- NKX6-1 | c.471G>T p.L157= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- PDZRN3 | c.1329C>T p.D443= | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as rs779662431, COSV55202349; called by muse, mutect2
- RFPL4A | c.705G>A p.G235= | Silent (SNP) | VAF 270/1641 reads (16%) | catalogued as rs1233522897, COSV70455215; called by muse, mutect2, varscan2
- THSD7B | c.4776T>C p.P1592= (on ENST00000272643; = p.P1590= on NM_001316349.2) | Silent (SNP) | VAF 324/741 reads (44%) | called by muse, mutect2, varscan2
- TRGV9 | c.210G>C p.V70= | Silent (SNP) | VAF 36/465 reads (8%) | catalogued as rs1257423494; called by muse, mutect2
- UNC80 | c.4827A>G p.A1609= | Silent (SNP) | VAF 41/77 reads (53%) | called by muse, mutect2, varscan2
- ANKRD17 | c.-40_-34dup | 5'UTR (INS) | VAF 20/46 reads (43%) | called by mutect2, varscan2
- APPL1 | c.*2071C>T | 3'UTR (SNP) | VAF 10/117 reads (9%) | called by muse, mutect2
- ARL10 | c.*6532C>T | 3'UTR (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- ASIC3 | chr7:151048335 C>T | 5'Flank (SNP) | VAF 35/191 reads (18%) | called by muse, mutect2, varscan2
- BDKRB2 | c.*6C>T | 3'UTR (SNP) | VAF 18/130 reads (14%) | catalogued as rs201405339; called by muse, mutect2, varscan2
- CD6 | c.-172T>G | 5'UTR (SNP) | VAF 112/281 reads (40%) | called by muse, mutect2, varscan2
- CDC14A | c.*228_*230del | 3'UTR (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel
- CDH7 | chr18:65884596 A>C | 3'Flank (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- CHURC1 | c.*143G>T | 3'UTR (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- CLDN5 | c.*415C>G | 3'UTR (SNP) | VAF 16/249 reads (6%) | called by muse, mutect2
- CTSO | c.*790del | 3'UTR (DEL) | VAF 23/58 reads (40%) | called by mutect2, pindel, varscan2
- DDB1 | c.1861+47T>A | Intron (SNP) | VAF 65/114 reads (57%) | called by muse, mutect2, varscan2
- DLEU1 | n.386-37T>C | Intron (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- DRG1 | c.*174C>T | 3'UTR (SNP) | VAF 38/89 reads (43%) | called by muse, mutect2, varscan2
- EFNB3 | c.*356G>A | 3'UTR (SNP) | VAF 13/218 reads (6%) | catalogued as rs1026711448; called by muse, mutect2
- EIF4G2 | c.*584C>T | 3'UTR (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- ERMAP | c.85+87C>T | Intron (SNP) | VAF 31/291 reads (11%) | called by muse, mutect2, varscan2
- ETV1 | chr7:13893447 T>A | 3'Flank (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- FAM102A | c.-210G>T | 5'UTR (SNP) | VAF 91/202 reads (45%) | called by muse, mutect2, varscan2
- GET4 | c.317-285A>G | Intron (SNP) | VAF 11/132 reads (8%) | called by muse, mutect2
- GREM2 | c.*1814C>A | 3'UTR (SNP) | VAF 9/215 reads (4%) | called by muse, mutect2
- KLF7 | c.*4691T>C | 3'UTR (SNP) | VAF 49/83 reads (59%) | called by muse, mutect2, varscan2
- LIMD1 | c.*3370C>T | 3'UTR (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- MINPP1 | c.638-214del | Intron (DEL) | VAF 9/24 reads (38%) | called by mutect2, pindel, varscan2
- MIR1972-2 | chr16:70034333 G>A | 3'Flank (SNP) | VAF 31/239 reads (13%) | catalogued as rs1035001649; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851252 T>C | 5'Flank (SNP) | VAF 101/232 reads (44%) | catalogued as rs555046741; called by muse, mutect2, varscan2
- NECTIN1 | c.*692G>A | 3'UTR (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2
- NUAK1 | c.*2460G>A | 3'UTR (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- PCDH7 | c.*78C>A | 3'UTR (SNP) | VAF 38/311 reads (12%) | called by muse, mutect2, varscan2
- PDE3A | c.*2936C>G | 3'UTR (SNP) | VAF 61/148 reads (41%) | called by muse, mutect2, varscan2
- PDZD3 | c.-95G>T | 5'UTR (SNP) | VAF 13/133 reads (10%) | catalogued as rs776495808; called by muse, mutect2
- POLR1A | chr2:86106033 G>A | 5'Flank (SNP) | VAF 50/94 reads (53%) | catalogued as rs985342388, COSV104379916, COSV99606239; called by muse, mutect2, varscan2
- PPARA | c.*8062G>C | 3'UTR (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- PRDM6 | c.*253C>A | 3'UTR (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- PROSER2 | c.*1364G>A | 3'UTR (SNP) | VAF 17/54 reads (31%) | catalogued as rs999328861; called by muse, mutect2, varscan2
- PSMA6 | c.684-30C>T | Intron (SNP) | VAF 40/255 reads (16%) | catalogued as rs560633080; called by muse, mutect2, varscan2
- RAP1GAP | c.*30A>G | 3'UTR (SNP) | VAF 69/138 reads (50%) | called by muse, mutect2, varscan2
- RCC2 | chr1:17407278 C>T | 3'Flank (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- REEP3 | c.*3595G>A | 3'UTR (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- S1PR3 | c.-147-2147G>T | Intron (SNP) | VAF 17/325 reads (5%) | called by muse, mutect2
- SAMD14 | c.*1772G>T | 3'UTR (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- SCUBE3 | c.*3232T>C | 3'UTR (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- SLC20A2 | c.*1106C>G | 3'UTR (SNP) | VAF 20/165 reads (12%) | called by muse, varscan2
- SORBS3 | c.1954+925T>G | Intron (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- SPRED1 | c.*2218G>T | 3'UTR (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 12/184 reads (7%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2
- TMEM170B | c.*2025T>C | 3'UTR (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- TRIM62 | c.*657del | 3'UTR (DEL) | VAF 17/194 reads (9%) | called by mutect2, pindel
- TRIM64B | c.*414T>G | 3'UTR (SNP) | VAF 17/99 reads (17%) | catalogued as rs1445192670; called by mutect2, varscan2
- UBR5 | c.*152A>G | 3'UTR (SNP) | VAF 36/67 reads (54%) | catalogued as COSV99639716; called by muse, mutect2, varscan2
- UBXN7 | c.*1309A>G | 3'UTR (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
- WDR38 | c.308-43C>T | Intron (SNP) | VAF 40/600 reads (7%) | catalogued as rs764750200, COSV62160750; called by muse, mutect2
- ZMAT4 | c.577+138G>A | Intron (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2
- ZNF716 | c.*651A>G | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
